Somatic mutation profile of tumor specimen TCGA-A4-8518-01A (aliquot TCGA-A4-8518-01A-11D-2396-08) from TCGA case TCGA-A4-8518, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 48.5 years (17,713 days).
Specimen TCGA-A4-8518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77720b2a-b5db-46d0-a41d-3a543b169860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8518-10A (Blood Derived Normal), aliquot TCGA-A4-8518-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/083cfbe7-c315-4b54-8bbc-9bade179faee

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRAG1 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70209978, COSV70210010; called by muse, mutect2, varscan2
- KCNK5 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs866296929, COSV100851951, COSV63988541; called by muse, mutect2, varscan2
- LMLN | c.91T>A p.W31R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs375365578; called by muse, mutect2, varscan2
- PREX2 | c.1906A>T p.I636F | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55751535; called by muse, mutect2
- TDRD6 | c.2382C>G p.N794K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV60173950; called by muse, mutect2, varscan2
- USP19 | c.2922del p.Y975Tfs*8 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | catalogued as COSV60048857; called by mutect2, pindel, varscan2
- ANAPC7 | c.1560A>G p.V520= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV71443700; called by muse, mutect2, varscan2
- KCNC4 | c.1893G>A p.L631= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV63925054; called by muse, mutect2, varscan2
- KCNH8 | c.600G>A p.P200= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as rs996252192, COSV60456908; called by muse, mutect2
- SLC16A14 | c.1107C>T p.I369= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1468493939, COSV54616855, COSV54618721; called by muse, mutect2, varscan2
- OBSCN | c.11659+4991C>G | Intron (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
